Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8438, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8438-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

1. Kidney, left (left radical nephrectomy): Renal cell carcinoma, chromophobe-type, with areas of high-grade sarcomatoid differentiation. Tumor approaches but does not go through the capsule. Vascular and ureteral margins are free of tumor. Adrenal gland, no tumor seen.
2. Lymph nodes, retroperitoneal (excision): Reactive lymph nodes with marked sinus histiocytosis, no tumor seen.

CLINICAL INFORMATION: HISTORY: LEFT RENAL MASS

PROCEDURE: PREOP DX: #LEFT RENAL MASS POSTOP DX: LEFT RENAL MASS OPERATIVE
FINDINGS: VERY LARGE LEFT RENAL MASS AND ENLARGED HILAR LYMPH NODES

SPECIMENS SUBMITTED: 1) KIDNEY, LEFT NEPHRECTOMY
2) RETRO PERITONEAL LYMPH NODE

GROSS DESCRIPTION: Received in two formalin containers labeled with the patient's name and medical record number, and as:

1. "Left kidney" is a large soft tissue specimen weighing 3,800 grams measuring 22 x 18 x 15 cm. The ureter is marked with yellow ink and the vessel is marked with blue ink. The adrenal gland is identified. Once cut, there is a large, extensively red mass lesion without gross evidence of fibrosis, scarring, or encapsulation. This mass lesion occupies a major portion of the specimen. There is a small rim of normal appearing renal tissue with a maximum dimension of 8 cm. For procurement, samples of both normal renal tissue and the mass lesion are sent to [REDACTED]. The specimen is placed in formalin but other portions are submitted in ethanol as a touch prep and also as electron microscopy. The special instructions are confirmatory for culture, frozen, and touch prep.

Patient Identification

[page 2 of 2]
Code of section for #1:

A - vascular edges

B-I - representative portions of tumor

J - normal-appearing renal parenchyma

K-S - tumor

T-U - adrenal gland

V-JJ - representative portions of tumor

KK - tumor fixed in 70% ethanol

LL-PP - tumor and/or kidney at capsule

2. "Retroperitoneal lymph nodes" is a tan soft tissue mass measuring 7.5 x 3.5 x 1.5 cm. Upon palpation, five nodes are appreciated, the largest measuring 2.5 x 1 x 1 cm and the smallest measuring 1 x 1 x 0.7 cm. The lymph nodes are serially sectioned.

Code of section for specimen 2:

A-B - representative section of largest lymph node

C-F - representative portions of the remaining lymph nodes

Reviewed By: SURGICAL PATH CASE CONF,

Patient Identification

Source: NCI Genomic Data Commons file c457f1a7-8d14-4539-9cb8-b708a224583c (TCGA-KM-8438.E26CB4D8-057E-43CE-9733-6C2B31E02C58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).